Somatic mutation profile of tumor specimen TCGA-VQ-A8DU-01A (aliquot TCGA-VQ-A8DU-01A-11D-A364-08) from TCGA case TCGA-VQ-A8DU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 63.1 years (23,042 days).
Specimen TCGA-VQ-A8DU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99e6cc30-b754-4c05-87e0-51736a702ef6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8DU-10A (Blood Derived Normal), aliquot TCGA-VQ-A8DU-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c0fca3b-28a1-49a1-920f-665cb2e8bc32

The open-access MAF lists 145 somatic variants for this specimen: 117 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 25, Nonsense Mutation 8, Frame Shift Del 3, RNA 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRF1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs578092914, CM023667, COSV100942502, COSV100942655; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 9/10 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2791T>A p.S931T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV101329892, COSV70032320; called by muse, mutect2, varscan2
- ABHD3 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as rs772556503, COSV56676679; called by muse, mutect2, varscan2
- ACTL7B | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs764691236, COSV101012482; called by muse, mutect2, varscan2
- ACY3 | c.194T>A p.V65E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99662850; called by muse, mutect2, varscan2
- ADAM17 | c.2125C>T p.H709Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs778028713, COSV100175987; called by muse, mutect2, varscan2
- ADAMTS13 | c.2581G>A p.G861R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1371570379, COSV63022254; called by muse, mutect2
- ARAP1 | c.1184G>A p.R395Q (on ENST00000393609 / NM_001040118.2; = p.R150Q on NM_015242.4) | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752313641, COSV100501460; called by muse, varscan2
- ASB18 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101293567; called by muse, mutect2, varscan2
- ATXN7L2 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs915397381, COSV60204156; called by muse, mutect2, varscan2
- BHLHE40 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99847888; called by muse, mutect2, varscan2
- BIRC3 | c.926G>A p.W309* | Nonsense Mutation (SNP) | VAF 36/208 reads (17%) | catalogued as COSV99679632; called by muse, mutect2, varscan2
- C1QTNF1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs148307780; called by muse, mutect2, varscan2
- CACNA1G | c.4018G>A p.A1340T | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.679); catalogued as COSV100661018; called by muse, mutect2, varscan2
- CACTIN | c.1680C>G p.S560R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99698193; called by muse, mutect2, varscan2
- CASP8AP2 | c.665G>T p.C222F | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs1276827074, COSV52746845, COSV99386701; called by muse, mutect2, varscan2
- CCDC178 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV55789393; called by muse, mutect2, varscan2
- CEP97 | c.2264A>G p.H755R | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100511499; called by muse, mutect2, varscan2
- CNGA2 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as rs969937452, COSV100323332; called by muse, mutect2, varscan2
- CNGA3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs149230055; called by muse, mutect2, varscan2
- CNTLN | c.532C>G p.Q178E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV52066545, COSV52078197, COSV99262425; called by muse, mutect2, varscan2
- COL12A1 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485218; called by muse, mutect2, varscan2
- COL14A1 | c.3191A>C p.K1064T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.315); catalogued as COSV99917644; called by muse, mutect2, varscan2
- COPS3 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV99253407; called by muse, mutect2
- CPNE3 | c.362G>C p.R121T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99547038; called by muse, mutect2, varscan2
- CSMD1 | c.1314T>A p.C438* (on ENST00000520002; = p.C437* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as COSV101212417; called by muse, mutect2, varscan2
- CSMD3 | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99821855, COSV99840686; called by muse, mutect2, varscan2
- CTIF | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs768247779, COSV99836657; called by muse, mutect2, varscan2
- CWC22 | c.1613G>C p.R538P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99843871; called by muse, mutect2, varscan2
- DCAF1 | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1316726091; called by muse, mutect2, varscan2
- DEFB119 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 59/235 reads (25%) | catalogued as rs773450020, COSV99489094; called by muse, mutect2, varscan2
- DNAI4 | c.2311G>T p.V771L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.31); catalogued as rs778167310, COSV100925479; called by muse, mutect2, varscan2
- EPDR1 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs369217258; called by muse, mutect2, varscan2
- EPHA3 | c.1095A>C p.K365N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as rs1197169173, COSV100342027, COSV60722723; called by muse, mutect2, varscan2
- FBXL20 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1179491065, COSV99233638; called by muse, mutect2, varscan2
- GALNT17 | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61153803; called by muse, mutect2, varscan2
- HDAC2 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100892527; called by muse, mutect2, varscan2
- HECW1 | c.4007A>C p.N1336T | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101222570; called by muse, mutect2, varscan2
- HMGB4 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs752852710, COSV53959095, COSV53979639; called by muse, mutect2, varscan2
- HMGCLL1 | c.731A>G p.E244G | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231217; called by mutect2, varscan2
- HPS6 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as COSV100154760, COSV100154933; called by muse, mutect2
- HSPA14 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs374837716, COSV65684541; called by muse, mutect2, varscan2
- HSPG2 | c.1617G>C p.Q539H | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.453); catalogued as COSV101012840; called by muse, mutect2, varscan2
- HTR2C | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.392); catalogued as COSV99347879; called by muse, mutect2, varscan2
- ILDR2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV99613047, COSV99613986; called by muse, mutect2, varscan2
- INO80 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV62737155; called by muse, mutect2, varscan2
- IRS4 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100929393; called by muse, mutect2, varscan2
- ITPKB | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); catalogued as COSV99683547; called by muse, mutect2, varscan2
- KCNA4 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs768852661, COSV60251924, COSV60255631; called by muse, mutect2, varscan2
- KCNAB2 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.066); catalogued as COSV99378483; called by muse, mutect2, varscan2
- KCNH7 | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV100033627; called by muse, mutect2, varscan2
- LAMC3 | c.3798A>C p.E1266D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100735867; called by muse, mutect2
- LARP7 | c.1576G>A p.G526S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100134937; called by muse, mutect2, varscan2
- LILRB1 | c.278A>G p.E93G (on ENST00000427581; = p.E57G on NM_006669.6) | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as COSV100206789; called by muse, mutect2, varscan2
- LRIT2 | c.812C>G p.T271S | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as COSV100258243, COSV99058547; called by muse, mutect2, varscan2
- MAGEC3 | c.1358G>T p.R453M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100024700; called by muse, mutect2, varscan2
- MAPKAP1 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99784246; called by muse, mutect2, varscan2
- MSH6 | c.2746T>C p.F916L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99314827; called by muse, mutect2, varscan2
- MSN | c.84G>C p.Q28H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV100814053; called by muse, mutect2, varscan2
- MTUS1 | c.170A>C p.D57A | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100028677; called by muse, mutect2, varscan2
- MUC15 | c.945A>C p.E315D | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV99846071, COSV99846078; called by muse, mutect2, varscan2
- MUC16 | c.42241T>G p.F14081V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV101109511; called by muse, mutect2, varscan2
- MUC16 | c.33247T>C p.S11083P | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV101197493; called by muse, mutect2, varscan2
- MYH4 | c.4215A>C p.E1405D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99700188; called by muse, mutect2, varscan2
- MYH7 | c.2474A>T p.K825M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100805595; called by muse, mutect2, varscan2
- NEB | c.3511T>G p.L1171V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99413866; called by muse, mutect2, varscan2
- NIF3L1 | c.172C>T p.P58S (on ENST00000409020 / NM_001369444.1; = p.P31S on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99626520; called by muse, mutect2, varscan2
- NOS1 | c.4180C>T p.R1394* | Nonsense Mutation (SNP) | VAF 129/227 reads (57%) | catalogued as rs751893456, COSV57606409; called by muse, mutect2, varscan2
- NRXN1 | c.3890T>G p.V1297G | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100639571; called by muse, mutect2, varscan2
- NUP98 | c.485T>A p.I162N | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100261386; called by muse, mutect2, varscan2
- OR52K2 | c.313T>A p.F105I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100355606; called by muse, mutect2, varscan2
- OR52M1 | c.917T>G p.L306R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1411424486, COSV100798530; called by muse, mutect2
- OR6N2 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as COSV100209922, COSV100210552; called by muse, mutect2, varscan2
- OR8J1 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100274822, COSV57317530; called by muse, mutect2, varscan2
- OSGEPL1 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs772012980, COSV99918263; called by muse, mutect2, varscan2
- P4HA2 | c.1526del p.G509Afs*18 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as COSV51324768; called by mutect2, pindel, varscan2
- PCDH17 | c.2596A>T p.M866L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV100931379; called by muse, mutect2, varscan2
- PCDHA8 | c.1205A>C p.K402T | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as COSV100970338; called by muse, mutect2
- PEX11A | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | catalogued as rs764851981, COSV100261377; called by muse, mutect2, varscan2
- PLPPR5 | c.312T>G p.I104M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV99586867; called by muse, mutect2, varscan2
- POGLUT3 | c.1146T>A p.Y382* | Nonsense Mutation (SNP) | VAF 45/108 reads (42%) | catalogued as COSV100052457; called by muse, mutect2, varscan2
- PPP1R10 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs370270748; called by muse, mutect2, varscan2
- PRKCI | c.790A>C p.S264R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99855599; called by muse, mutect2, varscan2
- PTCHD4 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100259704, COSV59792690; called by muse, mutect2, varscan2
- PUS3 | c.1172T>G p.V391G | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV99916725; called by muse, mutect2, varscan2
- QRSL1 | c.150del p.K50Nfs*19 | Frame Shift Del (DEL) | VAF 180/321 reads (56%) | catalogued as rs1472084942; called by mutect2, pindel, varscan2
- QTRT2 | c.788G>A p.C263Y | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs199827335; called by muse, mutect2, varscan2
- RASGRF1 | c.2771G>A p.R924Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs759233302, COSV101174250; called by muse, mutect2, varscan2
- RYR3 | c.9659A>C p.K3220T (on ENST00000389232; = p.K3221T on NM_001036.6) | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101211832; called by muse, mutect2, varscan2
- SCN3A | c.4496T>G p.L1499R | Missense Mutation (SNP) | VAF 117/355 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV51803725, COSV51811199; called by muse, mutect2, varscan2
- SDCCAG8 | c.1624A>T p.K542* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV100653728; called by muse, mutect2, varscan2
- SEMA5A | c.2114A>C p.K705T | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV101226825; called by muse, varscan2
- SEMA6C | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100501015; called by muse, mutect2, varscan2
- SLC13A5 | c.1036T>C p.W346R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99545606; called by muse, mutect2, varscan2
- SLC35F1 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as COSV100837387, COSV64506552; called by muse, mutect2, varscan2
- SLC35F2 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.402); catalogued as COSV99758422; called by muse, mutect2, varscan2
- SLC46A2 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs964363505, COSV100953419; called by muse, mutect2, varscan2
- SP100 | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV99892008; called by muse, mutect2
- SP140 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as rs1261082888, COSV100613265; called by muse, mutect2
- SV2B | c.778C>A p.H260N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV100370315; called by muse, mutect2, varscan2
- TARS2 | c.1616A>C p.K539T | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100945814; called by muse, mutect2, varscan2
- TGFB3 | c.1001A>G p.H334R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1021920873, COSV99472290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.41495T>G p.L13832R (on ENST00000591111; = p.L6408R on NM_003319.4) | Missense Mutation (SNP) | VAF 30/54 reads (56%) | PolyPhen probably damaging (0.999); catalogued as COSV100590614, COSV100594174; called by muse, mutect2, varscan2
- UFSP2 | c.1307A>C p.Q436P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99248804; called by muse, mutect2, varscan2
- UNC5D | c.2744T>C p.L915P | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99771359; called by muse, mutect2, varscan2
- VWF | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772466729, COSV54621841; called by muse, mutect2, varscan2
- WNK1 | c.2449C>A p.P817T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV100265931, COSV60033530; called by muse, mutect2, varscan2
- ZFHX4 | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV51454206, COSV51471359, COSV99257900; called by muse, mutect2, varscan2
- ZMYM5 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV100562491; called by muse, mutect2, varscan2
- ZNF521 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.838); catalogued as rs774175248, COSV64121536; called by muse, mutect2, varscan2
- ZNF846 | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs370153110; called by muse, mutect2, varscan2
- ZNF91 | c.2618A>C p.K873T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100322001; called by muse, mutect2, varscan2
- FZD6 | c.326_330delinsAA p.L109_I110delins* | Nonsense Mutation (DEL) | VAF 33/73 reads (45%) | called by pindel, varscan2*
- IGHV3-35 | c.161A>C p.N54T | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RETSAT | c.1500_1502del p.V501del | In Frame Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, varscan2
- SHISA2 | c.525del p.S176Rfs*38 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- AK9 | c.5553C>T p.S1851= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs749547321, COSV69849209; called by muse, mutect2, varscan2
- CELF2 | c.1113C>T p.G371= (on ENST00000416382 / NM_001025077.3; = p.G384= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV100256544; called by muse, mutect2, varscan2
- EPHB6 | c.600G>A p.R200= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as COSV101235904; called by muse, mutect2, varscan2
- GJD2 | c.489G>A p.E163= | Silent (SNP) | VAF 66/166 reads (40%) | catalogued as rs765039509, COSV51749890, COSV51750479; called by muse, mutect2, varscan2
- GPRC6A | c.909T>C p.D303= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100113938; called by muse, mutect2, varscan2
- GUCY2F | c.2184T>C p.S728= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV99484401; called by muse, mutect2, varscan2
- KCNA6 | c.96C>T p.G32= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1410308281, COSV54976995; called by muse, mutect2, varscan2
- KIAA0100 | c.2730A>G p.L910= | Silent (SNP) | VAF 119/257 reads (46%) | catalogued as rs1222895515, COSV101197195; called by muse, mutect2, varscan2
- LRRCC1 | c.2076G>T p.L692= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV100835247; called by muse, mutect2, varscan2
- NIPBL | c.4476A>G p.A1492= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99238334; called by muse, mutect2
- NR1D2 | c.315C>T p.V105= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as rs145963481, COSV100437242; called by muse, mutect2
- NTRK1 | c.1191G>A p.P397= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as rs756623123, COSV62327569; called by muse, mutect2, varscan2
- PLPPR4 | c.879C>T p.C293= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs142067527; called by muse, mutect2, varscan2
- PTGFRN | c.2116C>T p.L706= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV101277222; called by muse, mutect2, varscan2
- RAD51AP2 | c.1989G>A p.K663= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV101208269; called by muse, mutect2
- SCD5 | c.342C>T p.V114= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as rs772216954, COSV51102277; called by muse, mutect2, varscan2
- SESN1 | c.1155T>G p.L385= (on ENST00000356644 / NM_001199933.1; = p.L444= on NM_014454.3) | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV100122652; called by muse, mutect2, varscan2
- SLC13A4 | c.1176C>T p.T392= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1378343707, COSV100818772; called by muse, mutect2, varscan2
- SLC6A5 | c.1608G>A p.E536= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1565282792, COSV100116274, COSV54229556; called by muse, mutect2, varscan2
- SMAD3 | c.363C>T p.C121= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs760286714, COSV100528589; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPATA18 | c.1113T>C p.F371= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99729798; called by muse, mutect2, varscan2
- SPATA31D1 | c.4590T>G p.T1530= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100782404; called by muse, mutect2
- TEKT5 | c.1317G>A p.T439= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs536602809, COSV51586509; called by muse, mutect2, varscan2
- USP17L2 | c.66T>G p.S22= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100414495; called by muse, mutect2, varscan2
- ZNF536 | c.771G>A p.S257= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs1200417978, COSV62825240; called by muse, mutect2
- AC244258.1 | n.961A>G | RNA (SNP) | VAF 27/141 reads (19%) | catalogued as rs763656686; called by muse, mutect2, varscan2
- DCHS2 | n.3836A>G | RNA (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100600915; called by muse, mutect2, varscan2
- SUN1 | c.659-260A>T | Intron (SNP) | VAF 40/155 reads (26%) | called by muse, mutect2, varscan2
